MMRF case MMRF_1185 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6356f1f3-7d56-4464-b70c-84eb69b7262c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.0 years (24,830 days); ISS stage: III; Days to last known disease status: 1,713 days (4.7 years); Days to last follow up: 1,713 days (4.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 81 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 117 days; Days to treatment end: 117 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 117 days; Days to treatment end: 117 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 256 days; Days to treatment end: 1,211 days (3.3 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,713.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 233 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 1.85 g/L; Immunoglobulin M 0.63 g/L; Beta 2 Microglobulin 5.77 µg/mL; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.85 ×10⁹/L; Platelets 418 ×10⁹/L; Creatinine 335 µmol/L; Blood Urea Nitrogen 18.2 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 7.8 g/dL; Glucose 6.88 mmol/L; C-Reactive Protein 1.15 mg/dL.
- Day 93: Serum Free Immunoglobulin Light Chain, Kappa 1.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.44 mg/dL; Immunoglobulin G 5.98 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.78 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 154 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 5.72 mmol/L.
- Day 215 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 7.61 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.57 g/L; Beta 2 Microglobulin 3.51 µg/mL; Hemoglobin 8.8 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.61 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.58 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 6.27 mmol/L.
- Day 256: Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 7.42 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 9.42 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.35 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.55 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 6.99 mmol/L.
- Day 345 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.53 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.89 g/L; Beta 2 Microglobulin 3.87 µg/mL; Hemoglobin 8.56 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 137 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.55 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL; Glucose 4.62 mmol/L.
- Day 429 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.29 mg/dL; Immunoglobulin G 15.3 g/L; Immunoglobulin A 1.24 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 3.33 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 146 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 8.6 g/dL; Glucose 5.94 mmol/L.
- Day 529 (ECOG 1): Hemoglobin 7.44 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 132 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 5.5 mmol/L.
- Day 569: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.92 mg/dL; Immunoglobulin G 16.2 g/L; Immunoglobulin A 1.45 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 149 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 5.89 mmol/L.
- Day 750: Serum Free Immunoglobulin Light Chain, Kappa 4.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.22 mg/dL; Immunoglobulin G 16.1 g/L; Immunoglobulin A 2 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 105 ×10⁹/L; Creatinine 152 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 6 mmol/L.
- Day 845 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.33 mg/dL; Immunoglobulin G 18 g/L; Immunoglobulin A 2.68 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.56 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 170 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.53 mmol/L; Albumin 44 g/L; Total Protein 8.5 g/dL; Glucose 7.04 mmol/L.
- Day 925: Serum Free Immunoglobulin Light Chain, Kappa 4.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.62 mg/dL; Hemoglobin 7.07 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 147 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.58 mmol/L; Albumin 41 g/L; Total Protein 7.7 g/dL; Glucose 5.61 mmol/L.
- Day 1,030: Serum Free Immunoglobulin Light Chain, Kappa 6.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.22 mg/dL; Hemoglobin 7.13 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 5.5 mmol/L.
- Day 1,132: Hemoglobin 7.19 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 6.27 mmol/L.
- Day 1,209 (ECOG 1): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.32 mg/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 3.09 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 3.51 µg/mL; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.46 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 164 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 8.1 g/dL; Glucose 6.49 mmol/L.
- Day 1,317: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.48 mg/dL; Hemoglobin 8.99 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.6 mmol/L; Albumin 43 g/L; Total Protein 7.7 g/dL; Glucose 6.16 mmol/L.
- Day 1,453: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.18 mg/dL; Hemoglobin 8.8 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.48 mmol/L; Albumin 44 g/L; Total Protein 7.5 g/dL; Glucose 7.43 mmol/L.
- Day 1,517: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.79 mg/dL; Hemoglobin 9.3 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 155 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.58 mmol/L; Albumin 43 g/L; Total Protein 7.5 g/dL; Glucose 6.11 mmol/L.
- Day 1,573 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.69 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 1.68 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 3.85 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.71 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 144 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 5.17 mmol/L.
- Day 1,607: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.06 mg/dL; Beta 2 Microglobulin 0.43 µg/mL; Hemoglobin 9.42 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 140 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 7.3 g/dL; Glucose 5.94 mmol/L.

Other clinical attributes
- Day -9: Weight: 79 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (3 samples)
- Sample MMRF_1185_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_1185_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
- Sample MMRF_1185_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 429 days (1.2 years).
